Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JN-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD 0.3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS C64.9
J 2/28/14

Final Diagnosis

- A. RIGHT PARTIAL NEPHRECTOMY:
Oncocytic variant of papillary renal cell carcinoma, Fuhrman nuclear grade 2-3, confined to the kidney (See Comment and See Key Pathological Findings).
Parenchymal resection margin, free of tumor (tumor located a fraction of a mm from the margin).
Pathologic stage: pT1a NX MX.
- B. DEEP MARGIN:
Renal parenchyma, no tumor present.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

The tumor cells are arranged in papillae and tubules and exhibit moderate amount of pink eosinophilic cytoplasm. Areas of papillae formation with foamy histiocytes are present. There is a single layer of tumor cells with luminally placed nuclei. No nuclear stratification is identified. Immunohistochemical stains performed show the tumor cells to be strongly positive for cytokeratin 7, and E-Cadherin, focally positive for vimentin with weak and focal positivity for racemase. The tumor cells are negative for CD10, RCC and CD117.

Key Pathological Findings

Tumor type:	Oncocytic variant of papillary renal cell carcinoma
Nuclear grade:	Predominantly 2, focally 3
Tumor size:	3.2 x 3.2 x 2.3 cm
Pattern of growth:	Tubular and papillary
Renal capsule invasion:	Not identified
Invasive of perinephric adipose tissue:	Not applicable
Renal vein invasion:	Not applicable
Surgical margins:	Free of tumor
Lymphovascular invasion:	Not identified
Perineural invasion:	Not identified
Adrenal gland:	Not applicable
Lymph nodes:	Not applicable
Pathologic stage:	pT1a NX MX.

Specimen(s) Received

- A. RIGHT PARTIAL NEPHRECTOMY FS

[page 2 of 2]
B DEEP MARGIN FS

Clinical History

None provided.

Preoperative Diagnosis

Right renal mass.

Intraoperative Consultation

FSA1. RIGHT PARTIAL NEPHRECTOMY:
Oncocytic lesion.

FSB1. DEEP MARGIN:
Negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Part A is received fresh for frozen section consult, labeled "right partial nephrectomy: ink-margin" and consists of an oriented segment of renal tissue, 23.5 g, 5.1 x 3.7 x 2.9 cm. The capsule is intact and smooth with scant soft tissue (ink black); and the deep parenchymal margin is inked blue.

The cut surfaces exhibit a circumscribed pale tan lobulated rubbery tumor mass, 3.2 x 3.2 x 2.3 cm. The mass approximates the deep parenchymal margin, separated by a submillimeter of membrane. The mass is interspersed with fibrosis. Minimal focal cysts are noted, however, no necrosis or hemorrhage is identified. The normal parenchyma is dark tan and smooth. Representative sections are submitted as FSA1-A8 as labeled:

FSA1:	Frozen section of renal lesion with nearest capsule
A2-A3:	Cross section of renal lesion with fibrosis, bisected and mirror image sections submitted for Tissue Procurement Laboratory
A4-A5:	Cross section of renal lesion, bisected
A6-A7:	Cross section of renal lesion, bisected
A8:	Cross section of renal lesion.

The specimen is submitted for Tissue Procurement Laboratory.

B. Part B is received fresh for frozen section consultation, labeled "deep margin: ink-margin" and consists of an oriented dark tan renal sliver, 1 x 1 x 0.5 cm. The inked margin is re-inked blue. Sectioned perpendicular, the cut surfaces exhibit unremarkable smooth parenchyma. No lesion is grossly seen. The specimen is submitted entirely in FSB1.

The specimen is not submitted for Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file a4b10f00-f47a-473d-a6b4-6d337c72712f (TCGA-2Z-A9JN.4450C905-2199-4DF3-A17B-450736D6F403.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).